Somatic mutation profile of tumor specimen 0DI7V3 from CCDI case PBBVNN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Adrenal cortical adenoma, NOS; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 2.5 years (914 days).
Specimen 0DI7V3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7430633-6268-483a-92c6-fd0216bf367a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/164bbec7-ea5a-4dc2-9db2-d7ac51d981e3

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF599 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 52/1080 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs143039488; called by muse, mutect2
- KALRN | c.5504C>T p.S1835L (on ENST00000360013 / NM_001024660.4; = p.S138L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/1236 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2
- MON1B | c.442A>C p.S148R | Missense Mutation (SNP) | VAF 51/993 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- PEG3 | c.2583_2588del p.S862_I863del | In Frame Del (DEL) | VAF 113/644 reads (18%) | called by mutect2, varscan2
- PIK3C3 | c.2401C>T p.Q801* | Nonsense Mutation (SNP) | VAF 78/1694 reads (5%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 19/419 reads (5%) | called by muse, mutect2
